Somatic mutation profile of tumor specimen MBCProject_1527_T4_WES (aliquot MBCProject_1527_T4_WES_1) from CMI case MBCProject_1527, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 47.3 years (17,281 days).
Specimen MBCProject_1527_T4_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54d1f43b-1556-4dd8-a93d-a4d7e1e7e9f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1527_SALIVA (Saliva), aliquot MBCProject_1527_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ee89626-1c29-437f-b358-7a88619353ed

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Frame Shift Ins 2, Splice Site 2, Intron 2, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 52/129 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ATP10B | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59159762; called by muse, mutect2, varscan2
- GABBR1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 249/267 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63541730; called by muse, mutect2, varscan2
- GATA3 | c.1221dup p.P408Afs*99 | Frame Shift Ins (INS) | VAF 45/133 reads (34%) | catalogued as COSV100650835, COSV100651341, COSV60515158, COSV60515274, COSV60515375, COSV60517941; called by mutect2, pindel, varscan2
- GLS | c.1248+1G>A p.X416_splice | Splice Site (SNP) | VAF 47/124 reads (38%) | catalogued as rs1224829551; called by muse, mutect2, varscan2
- KLF17 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs766222742, COSV64856058; called by muse, mutect2, varscan2
- MCAM | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1036616901; called by muse, mutect2, varscan2
- PEAR1 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52776638; called by muse, mutect2, varscan2
- PIN1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981681899; called by muse, mutect2, varscan2
- PLCH2 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs1304062233; called by mutect2, varscan2
- PNPT1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as COSV99570316; called by muse, mutect2, varscan2
- RC3H1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as rs1186630957; called by muse, mutect2, varscan2
- RYR3 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as rs200621978, CM137597; called by mutect2, varscan2
- TMCC3 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs765186994; called by muse, mutect2, varscan2
- WRAP73 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs567342277; called by muse, mutect2, varscan2
- ARID1A | c.4268dup p.Q1424Sfs*21 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- FAM149B1 | c.1105C>A p.L369I | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HTR1A | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF26B | c.3103T>C p.S1035P | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA5 | c.7390G>A p.A2464T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LEMD1 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRC6 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MIA2 | c.645T>G p.N215K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RALGDS | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SET | c.173T>A p.L58H (on ENST00000372692 / NM_001374326.1; = p.L45H on NM_003011.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC4A1AP | c.1506+1G>A p.X502_splice | Splice Site (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2866C>G p.L956V (on ENST00000621492; = p.L922V on NM_025248.3) | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TJP1 | c.1492A>G p.I498V | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- TMEM39A | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VWC2 | c.824del p.N275Mfs*11 | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel, varscan2
- AKAP11 | c.3648C>A p.S1216= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- ARF3 | c.417C>T p.I139= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV99872986; called by muse, mutect2, varscan2
- IVL | c.819G>C p.L273= | Silent (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- KCNT2 | c.3249C>T p.I1083= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as COSV54106582, COSV54110303; called by muse, varscan2
- PIAS3 | c.738C>A p.P246= | Silent (SNP) | VAF 98/228 reads (43%) | called by muse, mutect2, varscan2
- TMEM39A | c.807C>A p.L269= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100052405; called by muse, mutect2, varscan2
- TNIK | c.111G>C p.G37= | Silent (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- USP16 | c.1686A>C p.L562= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- WDFY4 | c.3315C>T p.P1105= | Silent (SNP) | VAF 78/172 reads (45%) | called by muse, mutect2, varscan2
- ABCA13 | c.12070+39T>C | Intron (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- BSCL2 | chr11:62707245 G>T | 5'Flank (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- MFSD13A | c.828+704C>T | Intron (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- OR56B3P | n.312C>G | RNA (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
